Somatic mutation profile of tumor specimen TCGA-DG-A2KL-01A (aliquot TCGA-DG-A2KL-01A-11D-A17W-09) from TCGA case TCGA-DG-A2KL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 53.5 years (19,539 days).
Specimen TCGA-DG-A2KL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49e5fb95-7173-4cac-b7cb-0684b023bc39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DG-A2KL-10A (Blood Derived Normal), aliquot TCGA-DG-A2KL-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adfcbc14-51be-4e77-9900-f664c3fd7fef

The open-access MAF lists 206 somatic variants for this specimen: 131 protein-altering or splice-affecting, 66 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 66, Nonsense Mutation 8, Intron 6, Splice Site 6, RNA 2, Frame Shift Del 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD17B | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61007781; called by muse, mutect2, varscan2
- ADAMTS17 | c.2575C>T p.H859Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV51479012; called by muse, mutect2
- ADAMTS7 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1415163845, COSV66306987; called by muse, mutect2, varscan2
- ADAMTSL4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV54999234; called by muse, mutect2
- ADIPOR2 | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 11/85 reads (13%) | catalogued as COSV63946188; called by muse, mutect2, varscan2
- AGAP1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328244428, COSV58324497, COSV58333147; called by muse, mutect2, varscan2
- AHCTF1 | c.1600-1G>A p.X534_splice (on ENST00000366508; = p.X508_splice on NM_015446.5) | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV58249237; called by muse, mutect2, varscan2
- ARHGAP21 | c.2985G>C p.L995F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57605309; called by muse, mutect2, varscan2
- ATRX | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as COSV64875685; called by muse, mutect2, varscan2
- C16orf90 | c.122C>T p.P41L (on ENST00000399645 / NM_001353385.2; = p.P32L on NM_001080524.2) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as COSV68714449; called by muse, mutect2, varscan2
- CACNG8 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV54414568; called by muse, mutect2, varscan2
- CAPZA3 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56851990, COSV99856066; called by muse, mutect2, varscan2
- CCKBR | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58099194; called by muse, mutect2, varscan2
- CD19 | c.1543C>A p.R515S (on ENST00000324662 / NM_001178098.2; = p.R514S on NM_001770.6) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV61187877, COSV61188443; called by muse, mutect2, varscan2
- CDCA2 | c.1121-1G>C p.X374_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV57945694; called by muse, mutect2, varscan2
- CDHR2 | c.2409C>A p.D803E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56138039; called by muse, mutect2, varscan2
- CHFR | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57173990, COSV57178143; called by muse, mutect2, varscan2
- CLDN18 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs1261948319, COSV59302567; called by muse, mutect2, varscan2
- CLVS2 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.124); catalogued as COSV51561565; called by muse, mutect2, varscan2
- COMP | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM118530, COSV55874603; called by muse, mutect2, varscan2
- CRHR2 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59265065; called by muse, mutect2, varscan2
- CRYGS | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57192346; called by muse, mutect2, varscan2
- CSRP2 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60702475; called by muse, mutect2, varscan2
- CYP3A7 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs897612214, COSV60481380; called by muse, mutect2, varscan2
- DCLRE1A | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV63748598, COSV63748690; called by muse, mutect2, varscan2
- DDIT3 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs1565654145, COSV100007237, COSV56252157; called by muse, mutect2, varscan2
- DENND3 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV52803273; called by muse, mutect2
- DPP3 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV64756637; called by muse, mutect2, varscan2
- EPRS1 | c.3949G>C p.E1317Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV65098575; called by muse, mutect2, varscan2
- FAM222B | c.804C>G p.I268M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57930044; called by muse, mutect2, varscan2
- FAM43B | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV60579707; called by muse, mutect2, varscan2
- FPR2 | c.488T>G p.F163C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60672686; called by muse, mutect2, varscan2
- FSTL5 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as COSV60193115, COSV60221645; called by muse, mutect2, varscan2
- FZR1 | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100553446, COSV58051583; called by muse, mutect2, varscan2
- GLI3 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.251); catalogued as CM150058, COSV67887922; called by muse, mutect2, varscan2
- GNAO1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52613392; called by muse, mutect2, varscan2
- GPR107 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61279099; called by muse, mutect2, varscan2
- GPR137C | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as rs752405401, COSV58704829, COSV58707378; called by muse, mutect2, varscan2
- GRHPR | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs566239341, COSV58942080; called by muse, mutect2, varscan2
- H4C5 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV63486578, COSV63487346; called by muse, mutect2, varscan2
- HEPN1 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV53429924; called by muse, mutect2, varscan2
- HLA-DMA | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV66385692; called by muse, mutect2, varscan2
- IDH3A | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV55112689; called by muse, mutect2, varscan2
- IGHV1-24 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs367908320; called by muse, mutect2, varscan2
- IL11RA | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as COSV58840543; called by muse, mutect2, varscan2
- IL27RA | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs768013483, COSV54600471; called by muse, mutect2, varscan2
- ITPR2 | c.5581G>C p.E1861Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67268647; called by muse, mutect2, varscan2
- KCNA6 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs201895638, COSV99768506; called by muse, mutect2, varscan2
- KDM5A | c.3845G>A p.R1282H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs781474100, COSV66992127; called by muse, mutect2, varscan2
- KIAA1109 | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV52670674; called by muse, mutect2, varscan2
- KIAA1549 | c.4197G>C p.K1399N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54312606; called by muse, mutect2, varscan2
- KIAA1755 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs139310550; called by muse, mutect2, varscan2
- KIF24 | c.1901G>C p.R634T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61454642; called by muse, mutect2, varscan2
- LARP4B | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60221270; called by muse, mutect2, varscan2
- LLGL1 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138380942; called by muse, mutect2, varscan2
- LRBA | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201925309; called by muse, mutect2, varscan2
- LRRCC1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs758066481, COSV64483249; called by muse, mutect2, varscan2
- MAP3K9 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV67119645, COSV67121055; called by muse, mutect2, varscan2
- MAPK1 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53186174; called by muse, mutect2, varscan2
- MARK1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65067255; called by muse, mutect2, varscan2
- MAST1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52245965; called by muse, mutect2, varscan2
- MCEMP1 | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100365344; called by muse, mutect2
- ME2 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777347174, COSV58423056; called by muse, mutect2, varscan2
- MRGPRD | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV58422788, COSV58423091, COSV58423167; called by muse, mutect2, varscan2
- MROH8 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs1402102711, COSV54119577; called by muse, mutect2, varscan2
- MSH2 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs772662439, COSV51876328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBBP1A | c.3417G>A p.M1139I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV54597136; called by muse, mutect2, varscan2
- MYH10 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV52599961; called by muse, mutect2, varscan2
- NAB2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767681676, COSV55666108; called by mutect2, varscan2
- NCOA6 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); catalogued as rs755268427, COSV62863226; called by muse, mutect2, varscan2
- NEXMIF | c.3650G>A p.R1217H | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs143271748, COSV50028941; called by muse, mutect2, varscan2
- NFE2 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV56455235, COSV56455351; called by muse, mutect2, varscan2
- NIBAN1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV62284485; called by muse, mutect2, varscan2
- NOS2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs777393355, COSV58222388; called by muse, mutect2, varscan2
- OR10G3 | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV57810137; called by muse, mutect2, varscan2
- OR1J2 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58944284; called by muse, mutect2, varscan2
- OR52A1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs747955134, COSV100200481, COSV61092361; called by muse, mutect2, varscan2
- OR6B1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1320690798, COSV68770053; called by muse, mutect2, varscan2
- OR8B12 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV100172738, COSV60911594, COSV60912162; called by muse, mutect2, varscan2
- OR8U1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV56415131, COSV56415358; called by muse, varscan2
- OSBPL5 | c.1974C>G p.I658M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55141389; called by muse, mutect2
- PASD1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV64855051; called by muse, mutect2, varscan2
- PCDHA7 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.155); catalogued as COSV65343720; called by muse, mutect2, varscan2
- PCDHB11 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV53378199; called by muse, mutect2, varscan2
- PCOLCE2 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs552293480, COSV55998821; called by muse, mutect2, varscan2
- PDXDC1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 12/222 reads (5%) | catalogued as COSV100363050, COSV57907795; called by muse, mutect2
- PEAK1 | c.3375G>T p.Q1125H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56934391; called by muse, mutect2, varscan2
- PHLPP1 | c.2869G>C p.E957Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV53027683; called by muse, mutect2, varscan2
- PKHD1 | c.9204G>C p.M3068I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV61873180; called by muse, mutect2, varscan2
- PMFBP1 | c.2094G>C p.L698F (on ENST00000537465; = p.L693F on NM_031293.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV52823395; called by muse, mutect2, varscan2
- PNMA8B | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV100885377; called by muse, mutect2
- PNMA8B | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV100885378; called by muse, mutect2, varscan2
- PODXL2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764073288, COSV61064451; called by muse, mutect2, varscan2
- POM121 | c.3725G>A p.R1242Q (on ENST00000434423; = p.R977Q on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs782277773, COSV57514846; called by muse, mutect2, varscan2
- RALGAPA1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV51881862; called by muse, mutect2, varscan2
- RASGRF1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs1350393326, COSV67249880; called by muse, mutect2, varscan2
- RETREG2 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56087467; called by muse, mutect2, varscan2
- RXFP2 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53635130; called by muse, mutect2, varscan2
- SETMAR | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV62780705; called by muse, mutect2, varscan2
- SH3PXD2B | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs771397027, COSV61126477; called by muse, mutect2, varscan2
- SHROOM1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV60581116; called by muse, mutect2, varscan2
- SLC15A1 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764058347, COSV64731236; called by muse, mutect2, varscan2
- SLC4A5 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as rs922931802, COSV100697554; called by muse, mutect2
- SLC6A14 | c.508+2T>A p.X170_splice | Splice Site (SNP) | VAF 18/97 reads (19%) | catalogued as COSV64146894; called by muse, mutect2, varscan2
- SLMAP | c.1538C>G p.A513G (on ENST00000428312 / NM_001377924.1; = p.A575G on NM_007159.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV55846964; called by muse, mutect2, varscan2
- SPECC1 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs771693569, COSV54953178; called by muse, mutect2, varscan2
- SPTB | c.4984A>G p.I1662V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV67631479; called by muse, mutect2
- SURF6 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63292763; called by muse, mutect2, varscan2
- SYNE1 | c.7068C>G p.I2356M (on ENST00000367255 / NM_182961.4; = p.I2363M on NM_033071.3) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV54967584; called by muse, mutect2, varscan2
- TPCN1 | c.2246G>C p.R749T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as rs764272795, COSV100136802, COSV59234882; called by muse, mutect2, varscan2
- UBE2M | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs1488789980, COSV99448054; called by muse, mutect2, varscan2
- USP19 | c.824-1G>C p.X275_splice | Splice Site (SNP) | VAF 17/91 reads (19%) | catalogued as COSV59733011; called by muse, mutect2, varscan2
- USP49 | c.951G>C p.L317F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV51896717; called by muse, mutect2, varscan2
- VPS13A | c.7836G>T p.M2612I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV62428970, COSV62437135; called by muse, mutect2, varscan2
- VPS13D | c.5989C>A p.Q1997K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99166022; called by muse, mutect2, varscan2
- ZNF407 | c.2799G>C p.K933N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV55251061; called by muse, mutect2, varscan2
- ZNF479 | c.929C>G p.S310* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV58638051; called by muse, mutect2, varscan2
- ZNF521 | c.3061C>G p.R1021G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64125965, COSV64126253; called by muse, mutect2, varscan2
- ZNF527 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV62230336; called by muse, mutect2
- ZNF799 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 25/131 reads (19%) | catalogued as COSV101345263, COSV70122436; called by muse, mutect2, varscan2
- HNF1B | c.1617C>A p.S539R | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IGLV5-48 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- MAP3K12 | c.2436del p.E812Dfs*97 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel*, varscan2
- MMP24 | c.1635del p.W545* | Frame Shift Del (DEL) | VAF 39/94 reads (41%) | called by mutect2, pindel, varscan2
- OPA3 | c.277_294del p.G93_V98del | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- POTEM | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC47A2 | c.1413dup p.L472Afs*31 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- THSD1 | c.573C>A p.S191R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.149); called by muse, mutect2
- VPS13D | c.11653G>T p.G3885C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ABCA3 | c.1227C>A p.L409= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV100068256; called by muse, mutect2
- ADGRB3 | c.2064G>T p.G688= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV65393033; called by muse, mutect2, varscan2
- AL121899.2 | c.648G>A p.L216= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV67350466; called by muse, mutect2, varscan2
- ALPK1 | c.1710C>T p.F570= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV51584502; called by muse, mutect2, varscan2
- BEND3 | c.609G>A p.L203= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV64680975; called by muse, mutect2, varscan2
- CDH8 | c.1857C>T p.L619= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54854504, COSV54863781; called by muse, mutect2, varscan2
- CGRRF1 | c.405C>G p.L135= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs775596207, COSV53596576; called by muse, mutect2, varscan2
- CHD2 | c.3381C>T p.L1127= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs770233047, COSV67708626; called by muse, mutect2, varscan2
- COL12A1 | c.8307C>T p.I2769= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59394860; called by muse, mutect2, varscan2
- CPPED1 | c.894G>C p.L298= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV55496238, COSV55497373; called by muse, mutect2, varscan2
- CYP2S1 | c.807C>T p.V269= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs750138347, COSV59505890; called by muse, mutect2, varscan2
- DCHS1 | c.924C>T p.D308= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs760376436, COSV55034723; called by muse, mutect2, varscan2
- DPY19L1 | c.732C>T p.L244= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV60582013; called by muse, mutect2
- DPYD | c.2580G>A p.Q860= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV64591960; called by muse, mutect2, varscan2
- DSCAML1 | c.1131G>A p.V377= (on ENST00000321322; = p.V317= on NM_020693.4) | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV58389434; called by muse, mutect2, varscan2
- EARS2 | c.129C>T p.P43= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1379561389, COSV54841702; called by muse, mutect2, varscan2
- EPB41L1 | c.1104C>T p.I368= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs750666042, COSV52437166; called by muse, mutect2, varscan2
- FANCB | c.2202C>G p.L734= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100146498, COSV60759685; called by muse, mutect2, varscan2
- FRMPD3 | c.3453C>T p.L1151= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs748700557, COSV52189669; called by muse, mutect2, varscan2
- GLP2R | c.1257C>T p.F419= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV52324428; called by muse, mutect2, varscan2
- GNPAT | c.405G>A p.S135= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs768674644, COSV64153354; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR156 | c.1053G>A p.P351= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs530427940, COSV59939344; called by muse, mutect2, varscan2
- HHATL | c.1032C>T p.N344= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs555576124, COSV99825420; called by muse, mutect2
- KAT14 | c.1218C>G p.G406= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV66607501; called by muse, mutect2, varscan2
- L3MBTL1 | c.1374C>T p.T458= (on ENST00000418998 / NM_001377303.1; = p.T368= on NM_015478.7) | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs576853992, COSV64227987; called by muse, mutect2, varscan2
- LRRC23 | c.711G>C p.L237= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV50388300; called by muse, mutect2, varscan2
- LSM14B | c.120C>T p.L40= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV53379964, COSV53380231; called by muse, mutect2, varscan2
- MADD | c.949C>T p.L317= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV60623657; called by muse, mutect2, varscan2
- MAGEB1 | c.516C>T p.G172= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV66775679; called by muse, mutect2, varscan2
- MAGEC2 | c.207G>A p.E69= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99909499; called by muse, mutect2
- MCHR2 | c.39C>T p.A13= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs374330201; called by muse, mutect2, varscan2
- MICU2 | c.195T>C p.F65= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1445069654, COSV66673846; called by muse, mutect2, varscan2
- MRPL20 | c.339C>T p.F113= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV61224174, COSV61224279; called by muse, mutect2, varscan2
- MS4A14 | c.858T>A p.P286= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55734593; called by muse, mutect2, varscan2
- MYOM2 | c.939C>T p.R313= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs139950018; called by muse, mutect2, varscan2
- NOP9 | c.186G>A p.L62= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV55383942; called by muse, mutect2
- NTM | c.456T>C p.N152= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV66178832; called by muse, mutect2, varscan2
- OR2L3 | c.141C>T p.L47= | Silent (SNP) | VAF 38/272 reads (14%) | catalogued as COSV63455089; called by muse, mutect2, varscan2
- OR52L1 | c.237C>G p.L79= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV59986850; called by muse, mutect2, varscan2
- OR7G1 | c.312C>G p.V104= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53317559; called by muse, mutect2, varscan2
- OSBP2 | c.1188C>T p.R396= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs143970004; called by muse, mutect2, varscan2
- PCDHA7 | c.1566G>A p.P522= | Silent (SNP) | VAF 56/277 reads (20%) | catalogued as rs781865209, COSV65342977; called by muse, mutect2, varscan2
- PEG3 | c.3057C>T p.Y1019= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs756262819, COSV55631928; called by muse, mutect2, varscan2
- PUM1 | c.54C>T p.F18= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs541850603, COSV99927783; called by muse, mutect2, varscan2
- RNH1 | c.1236C>T p.D412= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs752335636, COSV57278024; called by muse, mutect2, varscan2
- SACS | c.9912C>G p.L3304= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as CD087728, COSV66539039, COSV66539697; called by muse, mutect2, varscan2
- SEMA4F | c.1404C>T p.I468= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs764738019, COSV60283102; called by muse, mutect2, varscan2
- SERPINB1 | c.729G>A p.L243= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV66313700; called by muse, mutect2, varscan2
- SETD2 | c.3414G>A p.E1138= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100338616, COSV57449014; called by muse, mutect2, varscan2
- SHOC2 | c.1572G>A p.L524= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54621563; called by muse, mutect2, varscan2
- SLC14A2 | c.1260C>T p.F420= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV54908534; called by muse, mutect2, varscan2
- SLC2A9 | c.1368C>T p.T456= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs375423927; ClinVar: benign; called by muse, mutect2, varscan2
- SLC38A10 | c.1624C>T p.L542= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55844987; called by muse, mutect2, varscan2
- SPEN | c.5619G>A p.E1873= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV65361212; called by muse, mutect2, varscan2
- SPEN | c.6012G>A p.P2004= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs146430628; called by muse, mutect2, varscan2
- TMEM184C | c.804G>A p.L268= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV56853508, COSV99669638; called by muse, mutect2, varscan2
- TMPRSS9 | c.2217C>A p.I739= (on ENST00000648592; = p.I705= on NM_182973.2) | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs780210816, COSV53114234, COSV53114642; called by muse, mutect2, varscan2
- TRIM2 | c.843G>A p.L281= (on ENST00000437508; = p.L308= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV58633059; called by muse, mutect2, varscan2
- TTPA | c.711C>T p.F237= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs771738459, COSV52646493; ClinVar: likely benign; called by muse, mutect2, varscan2
- UMOD | c.1311C>T p.T437= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs748219272, COSV56774511; called by muse, mutect2, varscan2
- VPS13D | c.8793C>T p.L2931= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs768184548, COSV99166026; called by muse, varscan2
- ZNF366 | c.954C>T p.F318= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV59215223; called by muse, mutect2, varscan2
- ZNF395 | c.43C>T p.L15= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1471567868, COSV60428418; called by muse, mutect2, varscan2
- ZNF556 | c.837C>T p.I279= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs1376920531, COSV56911949; called by muse, mutect2, varscan2
- ZNF77 | c.711G>A p.Q237= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV58821802; called by muse, mutect2, varscan2
- ZNF780A | c.1119C>T p.L373= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs761543916, COSV61815363; called by muse, mutect2
- AP2A2 | c.*976G>C | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100172726; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35721C>T | Intron (SNP) | VAF 25/132 reads (19%) | catalogued as rs770327978, COSV61627239; called by muse, mutect2, varscan2
- CDKL1 | c.171+17997C>T | Intron (SNP) | VAF 17/110 reads (15%) | catalogued as COSV53579332; called by muse, mutect2, varscan2
- CR1 | c.487+12067G>A | Intron (SNP) | VAF 19/176 reads (11%) | catalogued as rs533647702, COSV65457892; called by muse, mutect2, varscan2
- LAMA4 | c.195+109G>C | Intron (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54569555; called by muse, mutect2, varscan2
- RPL23A | c.210-99A>T | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as COSV52644273; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2234G>A | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as COSV54096057; called by muse, mutect2, varscan2
- ZNF658B | n.2063C>G | RNA (SNP) | VAF 20/131 reads (15%) | catalogued as rs1231537949; called by muse, mutect2, varscan2
- ZNF658B | n.966C>G | RNA (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
